Gene-level copy-number profile of tumor specimen ALCH-AEUQ-TTP1-A from ALCHEMIST case ALCH-AEUQ, project ALCHEMIST-ALCH (Adjuvant Lung Cancer Enrichment Marker Identification and Sequencing Trial). Sex at birth: female; Primary diagnosis: Adenocarcinoma, NOS; Age at diagnosis: 68.4 years (24,984 days).
Specimen ALCH-AEUQ-TTP1-A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file 61a44821-29ad-45be-89d1-b69a5e348903.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator ALCH-AEUQ-NB1-A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 2,232 have no estimate.
https://portal.gdc.cancer.gov/files/726e1bff-400c-4380-8b93-e9b39aa4c7ca

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 9; copy number 1: 13,011; copy number 2: 42,884; copy number 3: 2,225; copy number 4: 43; copy number 5: 67; copy number 6: 107; copy number 7: 45.

Homozygous deletions (total copy number 0; autosomes only): 9 genes in 2 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr15:75,639,085–75,712,848, 7 genes (within-gene range 0–2): IMP3, AC105020.6, AC105020.5, SNX33, CSPG4, AC105020.4, AC105020.1.
- chr17:18,476,737–18,506,313, 2 genes: LGALS9C, NOS2P2.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 219 genes in 3 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr7:25,118,656–25,180,356, 2 genes, copy number 5: CYCS, C7orf31.
- chr7:29,650,227–32,894,131, 65 genes, copy number 5 (within-gene range 4–9) (broad region; genes not listed).
- chr7:53,490,148–62,275,678, 152 genes, copy number 6–7 (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 12,997. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
